Gene-level copy-number profile of tumor specimen TCGA-DD-A11C-01A from TCGA case TCGA-DD-A11C, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 69.5 years (25,403 days).
Specimen TCGA-DD-A11C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.d7b9e101-bf37-4267-99b7-264915f0554e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A11C-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/32244e9d-c5f4-4760-90dd-4f12ee4b674c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 330; copy number 2: 6,575; copy number 3: 12,972; copy number 4: 26,645; copy number 5: 5,997; copy number 6: 5,507; copy number 7: 90; copy number 8: 450; copy number 9: 1,162; copy number 10: 33; copy number 11: 3; copy number 13: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A11C-01A-11D-A12Y-01): tumor purity 0.88, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:49,890,591–50,125,720, 15 genes: CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5.
- chr13:50,082,295–50,128,463, 4 genes: AL137060.6, RPL18P10, AL137060.1, AL137060.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,205 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:156,893,698–205,134,950, 996 genes, copy number 9–10 (broad region; genes not listed).
- chr1:206,635,536–213,794,587, 158 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).
- chr2:227,221,052–227,561,217, 6 genes, copy number 9 (within-gene range 5–9): MFF-DT, MFF, TM4SF20, SCYGR1, MIR5703, AGFG1.
- chr3:41,246,599–41,962,130, 3 genes, copy number 11 (within-gene range 5–11): ULK4, AC099537.1, RN7SKP58.
- chr3:187,932,764–188,154,057, 6 genes, copy number 13: AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2.
- chr3:188,178,543–188,180,812, 1 gene, copy number 13: FLJ42393.
- chr8:122,781,655–123,416,350, 25 genes, copy number 9 (within-gene range 6–9): ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, AC068228.3, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2.
- chr12:12,289,227–12,289,329, 1 gene, copy number 10: RNU6-318P.
- chr16:24,610,209–24,827,632, 1 gene, copy number 9 (within-gene range 6–9): TNRC6A.
- chr20:37,492,472–37,683,234, 8 genes, copy number 10: BLCAP, NNAT, AL109614.1, PPIAP3, LINC01746, GLRXP1, LINC00489, AL162293.1.

Autosomal genes at a single copy (total copy number 1): 330. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
